Somatic mutation profile of tumor specimen C3L-05554-02 (aliquot CPT0287450006) from CPTAC case C3L-05554, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 74.6 years (27,238 days).
Specimen C3L-05554-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Back; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db1cf832-1ee8-40d7-9c56-2dd1ae8b0527.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05554-31 (Blood Derived Normal), aliquot CPT0287420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad7c0141-1613-4467-8646-561bbb8ca239

The open-access MAF lists 842 somatic variants for this specimen: 558 protein-altering or splice-affecting, 248 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 512, Silent 248, Nonsense Mutation 36, Intron 17, 5'Flank 8, 3'UTR 5, Splice Region 4, RNA 3, Frame Shift Del 2, 3'Flank 2, Splice Site 2, Frame Shift Ins 2.

Variants (750 of 842; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPLANE1 | c.*2480C>T | 3'UTR (SNP) | VAF 90/364 reads (25%) | catalogued as rs375009168, CM141804, COSV99950416; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 60/216 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.2869C>T p.P957S (on ENST00000614293; = p.P927S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs576670735; called by muse, mutect2, varscan2
- ABCB8 | c.385G>A p.G129R (on ENST00000297504 / NM_001282291.2; = p.G112R on NM_007188.5) | Missense Mutation (SNP) | VAF 98/476 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV52503551, COSV99874277; called by muse, mutect2, varscan2
- ABLIM1 | c.2009C>T p.T670I | Missense Mutation (SNP) | VAF 87/171 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV53312413; called by muse, mutect2, varscan2
- ACOD1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 79/268 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66291285; called by muse, mutect2, varscan2
- ACOX1 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs752219452; called by muse, mutect2, varscan2
- ADAMTS16 | c.3182C>T p.S1061F | Missense Mutation (SNP) | VAF 78/209 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV56981887; called by muse, mutect2, varscan2
- ADAMTS18 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 25/344 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV51420088; called by muse, mutect2
- ADARB2 | c.2069G>A p.G690E | Missense Mutation (SNP) | VAF 102/215 reads (47%) | SIFT tolerated (0.9); PolyPhen benign (0.038); catalogued as rs1398181270; called by muse, mutect2, varscan2
- ADGRV1 | c.6229G>A p.E2077K | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.08); catalogued as rs200372116; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.15916G>A p.G5306R | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99081270; called by muse, mutect2
- ADRA1B | c.25C>T p.H9Y | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.043); catalogued as rs202245167; called by muse, mutect2, varscan2
- AHCYL2 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 39/259 reads (15%) | catalogued as COSV61486303; called by muse, mutect2, varscan2
- AIM2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 137/347 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.429); catalogued as COSV63699826; called by muse, mutect2, varscan2
- AIRE | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 79/317 reads (25%) | catalogued as rs1239318349, COSV99380954; called by muse, mutect2, varscan2
- AKNAD1 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs751500049, COSV62197104; called by muse, mutect2, varscan2
- AL592490.1 | c.1256T>G p.V419G | Missense Mutation (SNP) | VAF 30/377 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV101308123; called by muse, mutect2
- ALB | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV55740248; called by muse, mutect2, varscan2
- ALG13 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as rs767326994, COSV52636707; called by muse, mutect2, varscan2
- ALOX15B | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV66480168; called by muse, mutect2, varscan2
- ALPK2 | c.2437G>A p.G813R | Missense Mutation (SNP) | VAF 108/415 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV64497803; called by muse, mutect2, varscan2
- ALPK2 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 89/287 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs866329445; called by muse, varscan2
- AMBN | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 87/247 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as rs866268583; called by muse, mutect2, varscan2
- ANGPT1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.15); catalogued as rs149379021, COSV52460175; called by muse, mutect2, varscan2
- ANO10 | c.1769A>T p.D590V | Missense Mutation (SNP) | VAF 79/304 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs773162169, COSV99428029; called by muse, mutect2, varscan2
- AOC1 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 122/399 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as COSV62868353; called by muse, mutect2, varscan2
- APBB1IP | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 62/167 reads (37%) | catalogued as COSV66132496; called by muse, mutect2, varscan2
- ARMC4 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53463589; called by muse, mutect2, varscan2
- ASXL3 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52463987; called by muse, mutect2
- ATP1A1 | c.2200A>G p.M734V | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs1221578816; called by muse, mutect2
- ATXN7 | c.2408C>T p.S803F | Missense Mutation (SNP) | VAF 99/317 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765271901, COSV55749083; called by muse, mutect2, varscan2
- BDP1 | c.5479C>T p.R1827C | Missense Mutation (SNP) | VAF 113/388 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs1441660115, COSV62430653; called by muse, mutect2, varscan2
- BOD1L1 | c.5543C>T p.P1848L | Missense Mutation (SNP) | VAF 144/440 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs1433381682; called by muse, mutect2, varscan2
- BRD4 | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.012); catalogued as rs752109526; called by muse, mutect2, varscan2
- C11orf95 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 85/307 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1047109729; called by muse, mutect2, varscan2
- CACNA1F | c.4085G>A p.R1362Q | Missense Mutation (SNP) | VAF 120/376 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs375658952, COSV59903088; called by muse, mutect2, varscan2
- CALCRL | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149634296; called by muse, mutect2, varscan2
- CATIP | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 105/303 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99179687; called by muse, mutect2, varscan2
- CCDC168 | c.13978C>T p.L4660F | Missense Mutation (SNP) | VAF 101/331 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs1171603205, COSV100487745; called by muse, mutect2, varscan2
- CCDC68 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV61603145; called by muse, mutect2, varscan2
- CCDC85A | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 123/381 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.272); catalogued as rs1313571172; called by muse, mutect2, varscan2
- CD163 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.718); catalogued as COSV100775948; called by muse, mutect2, varscan2
- CD163L1 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.099); catalogued as rs761623370, COSV58015024; called by muse, mutect2, varscan2
- CDCA7L | c.36A>C p.E12D | Missense Mutation (SNP) | VAF 24/301 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs772671986; called by muse, mutect2
- CDK12 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71000118; called by muse, mutect2
- CDKN2A | c.367C>G p.H123D | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58709909; called by muse, mutect2, varscan2
- CEACAM3 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1214752442; called by muse, mutect2, varscan2
- CEP164 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1006672566; called by muse, mutect2, varscan2
- CFAP52 | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as rs267605111, COSV55348463; called by muse, mutect2, varscan2
- CFH | c.2855G>A p.G952E | Missense Mutation (SNP) | VAF 109/373 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV66411376; called by muse, mutect2, varscan2
- CFHR2 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 84/372 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs773697180, COSV100804194, COSV66380861; called by muse, mutect2
- CHGA | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 114/345 reads (33%) | catalogued as rs751314415, COSV99380948; called by muse, mutect2, varscan2
- CLEC3A | c.590G>A p.R197K (on ENST00000651443; = p.R188K on NM_005752.6) | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as CM142342, COSV55220068; called by muse, mutect2, varscan2
- CNGA3 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 66/346 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1338257190; called by muse, mutect2, varscan2
- CNTNAP2 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV62144663, COSV62167074; called by muse, mutect2
- CNTNAP2 | c.1087A>T p.N363Y | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1211111176; called by muse, mutect2
- CNTNAP4 | c.3200C>T p.S1067F | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271815, COSV56671209; called by muse, mutect2, varscan2
- CNTNAP5 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 131/364 reads (36%) | catalogued as rs1447158750, COSV70472787; called by muse, mutect2, varscan2
- COL4A5 | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 111/332 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.686); catalogued as COSV60355694; called by muse, mutect2, varscan2
- COL6A6 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 73/339 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV62036639; called by muse, mutect2, varscan2
- CPXM2 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 130/295 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV53855569; called by muse, mutect2, varscan2
- CRACR2B | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 122/426 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1238865149; called by muse, varscan2
- CRB1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 182/369 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.494); catalogued as COSV100958319; called by muse, mutect2, varscan2
- CSMD2 | c.9000G>A p.W3000* | Nonsense Mutation (SNP) | VAF 49/205 reads (24%) | catalogued as COSV53968534; called by muse, mutect2, varscan2
- CTAGE1 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as rs267605127, COSV66942971; called by muse, mutect2, varscan2
- CTCFL | c.1169G>A p.R390K | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs1181781982; called by muse, mutect2, varscan2
- CTNNA3 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 106/213 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV65602250; called by muse, mutect2, varscan2
- CYP1A1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 137/401 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs776797048, COSV65697433; called by muse, mutect2, varscan2
- DAPP1 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 86/283 reads (30%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.011); catalogued as COSV56453702; called by muse, mutect2, varscan2
- DAW1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 90/261 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59363580; called by muse, mutect2, varscan2
- DCLK2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1230886415, COSV56203727; called by muse, mutect2, varscan2
- DCST1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 173/436 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as rs748373788, COSV55056270; called by muse, mutect2, varscan2
- DDX60L | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 88/273 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52708528; called by muse, mutect2, varscan2
- DEFB105A | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 27/472 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100068731; called by muse, mutect2
- DES | c.1374C>T p.V458= | Splice Region (SNP) | VAF 70/332 reads (21%) | catalogued as rs727502952; ClinVar: likely benign; called by muse, mutect2, varscan2
- DIS3L2 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs745989142, COSV56054679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLC1 | c.1823C>T p.P608L (on ENST00000276297 / NM_001348081.2; = p.P171L on NM_006094.5) | Missense Mutation (SNP) | VAF 177/491 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs753440066; called by muse, mutect2, varscan2
- DMP1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 126/384 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs149078199; called by muse, mutect2, varscan2
- DNAH10 | c.4477G>A p.E1493K (on ENST00000409039; = p.E1432K on NM_207437.3) | Missense Mutation (SNP) | VAF 113/367 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs373563221, COSV68989561; called by muse, mutect2, varscan2
- DNAH5 | c.4420G>A p.D1474N | Missense Mutation (SNP) | VAF 95/334 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.789); catalogued as COSV54254061; called by muse, mutect2, varscan2
- DNAH7 | c.5936G>A p.G1979E | Missense Mutation (SNP) | VAF 77/274 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765588; called by muse, mutect2, varscan2
- DNM3 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 140/338 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62470169; called by muse, mutect2, varscan2
- DSCAM | c.4544C>T p.P1515L | Missense Mutation (SNP) | VAF 34/438 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs1426326317, COSV68029055; called by muse, mutect2
- DTX3L | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 27/371 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1470378190; called by muse, mutect2
- EFTUD2 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 99/329 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs372890927; called by muse, mutect2, varscan2
- EPHA7 | c.2112G>A p.G704= | Splice Region (SNP) | VAF 61/122 reads (50%) | catalogued as COSV65187000; called by muse, mutect2, varscan2
- FABP7 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62956980; called by muse, mutect2, varscan2
- FAM135B | c.3455G>A p.S1152N | Missense Mutation (SNP) | VAF 84/304 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs980242553, COSV99427159; called by muse, mutect2
- FAM135B | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 86/258 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248147089, COSV52744579; called by muse, mutect2, varscan2
- FAM160A2 | c.1894C>T p.P632S (on ENST00000449352 / NM_001098794.2; = p.P646S on NM_032127.4) | Missense Mutation (SNP) | VAF 106/339 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs561748424; called by muse, mutect2, varscan2
- FAM83C | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 111/415 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV65582155; called by muse, mutect2, varscan2
- FBH1 | c.565C>T p.P189S (on ENST00000362091 / NM_178150.3; = p.P240S on NM_032807.4) | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV62984769; called by muse, mutect2, varscan2
- FFAR1 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 146/438 reads (33%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.943); catalogued as rs200829130, COSV50052941; called by muse, varscan2
- FGF4 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 139/417 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1424999450; called by muse, mutect2, varscan2
- FMR1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 91/379 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV54422001, COSV99029106; called by muse, mutect2, varscan2
- FSD2 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs768603880; called by muse, mutect2, varscan2
- GC | c.1395G>A p.E465= | Splice Region (SNP) | VAF 17/130 reads (13%) | catalogued as rs140971733; called by mutect2, varscan2
- GCH1 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 76/218 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1204984727; called by muse, mutect2, varscan2
- GIMAP1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 116/380 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV56188929; called by muse, mutect2, varscan2
- GLI1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 91/348 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV57357951; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 149/870 reads (17%) | SIFT tolerated, low confidence (0.09); catalogued as rs1412783262; called by muse, mutect2, varscan2
- GOLGA8S | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 18/321 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV71846822; called by muse, mutect2
- GPC3 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 98/402 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs199778216; called by muse, mutect2, varscan2
- GPT | c.1398C>T p.F466= | Splice Region (SNP) | VAF 77/314 reads (25%) | catalogued as rs763542493, COSV52954369; called by muse, mutect2, varscan2
- GREB1 | c.3230C>A p.P1077H | Missense Mutation (SNP) | VAF 87/328 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs201714486, COSV52194420; called by muse, mutect2, varscan2
- GRID2 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1230071122; called by muse, mutect2, varscan2
- GRM5 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 107/361 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV59601513, COSV59603490; called by muse, mutect2, varscan2
- H2AC1 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV51237697; called by muse, mutect2, varscan2
- HAP1 | c.1553C>T p.S518F (on ENST00000310778 / NM_001367460.1; = p.S466F on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV57877721; called by muse, mutect2, varscan2
- HORMAD1 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 95/262 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs1166641975, COSV55047262, COSV55047593; called by muse, mutect2, varscan2
- HSFX2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 91/368 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs1464113515; called by muse, mutect2, varscan2
- IGF2BP1 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1374084344, COSV51730173, COSV51736274, COSV99288339; called by muse, mutect2, varscan2
- IL1R2 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1299459804, COSV60205654; called by muse, mutect2, varscan2
- IL37 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761253599, COSV54490876; called by muse, mutect2, varscan2
- IRF2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 70/258 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1249128082; called by muse, mutect2, varscan2
- ISX | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372031013; called by muse, mutect2, varscan2
- ITGAM | c.2525G>A p.R842Q (on ENST00000648685 / NM_001145808.2; = p.R841Q on NM_000632.4) | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs773006854, COSV54936404; called by muse, mutect2, varscan2
- ITGB4 | c.3130G>A p.G1044S | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748470495; called by muse, mutect2, varscan2
- ITIH5 | c.2212C>G p.R738G | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53663301; called by muse, mutect2, varscan2
- ITPR1 | c.1868G>A p.R623Q (on ENST00000354582; = p.R608Q on NM_002222.7) | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771580620, COSV56981520; called by muse, mutect2, varscan2
- ITPR2 | c.3740G>A p.R1247Q | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.309); catalogued as rs775575901, COSV67268231; called by muse, mutect2, varscan2
- KCNB1 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 127/408 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.011); catalogued as rs1569016783; called by muse, mutect2, varscan2
- KCNH1 | c.1772G>A p.R591Q (on ENST00000271751 / NM_172362.3; = p.R564Q on NM_002238.4) | Missense Mutation (SNP) | VAF 207/549 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370210778, COSV99657141; called by muse, mutect2, varscan2
- KDF1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 141/348 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); catalogued as rs771599585, COSV57670773; called by muse, mutect2, varscan2
- KIAA1217 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 123/232 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56819605; called by muse, mutect2, varscan2
- KIF2B | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.081); catalogued as rs1364750447; called by muse, mutect2
- KIF7 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 93/513 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs886051539; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF7 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 91/518 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67999367; called by muse, mutect2, varscan2
- KLHL32 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 123/247 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV65112235; called by muse, mutect2, varscan2
- KRT28 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as rs200061404, COSV60683815; called by muse, mutect2, varscan2
- KRT38 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 69/290 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55847288; called by muse, mutect2, varscan2
- LDLRAD1 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 99/335 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1456182734; called by muse, mutect2, varscan2
- LHCGR | c.1160G>A p.S387N | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54293252; called by muse, mutect2, varscan2
- LILRB1 | c.1640G>A p.R547K (on ENST00000427581; = p.R497K on NM_006669.6) | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.075); catalogued as COSV100207040; called by muse, mutect2, varscan2
- LMOD3 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 97/290 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs754255126; called by muse, mutect2, varscan2
- LRIT3 | c.631A>T p.K211* | Nonsense Mutation (SNP) | VAF 64/203 reads (32%) | catalogued as rs749820861; called by muse, mutect2, varscan2
- LRRC18 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 94/202 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138280112, COSV99630965; called by muse, mutect2, varscan2
- MAPT | c.1312C>T p.P438S (on ENST00000262410 / NM_001377265.1; = p.P363S on NM_016835.4) | Missense Mutation (SNP) | VAF 132/458 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.113); catalogued as rs751739883; called by muse, mutect2, varscan2
- MARCO | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 87/283 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59054615; called by muse, mutect2, varscan2
- MEGF8 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 46/536 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1382077675; called by muse, mutect2
- METTL17 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 98/292 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs140536845, COSV59557354; called by muse, mutect2, varscan2
- MIA2 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99696693; called by muse, mutect2, varscan2
- MMP11 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 105/512 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs141794324, COSV53157926, COSV53157966; called by muse, mutect2, varscan2
- MN1 | c.3787G>A p.D1263N | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs765586902; called by muse, mutect2, varscan2
- MTERF1 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 32/401 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1200008060; called by muse, mutect2
- MUC16 | c.23912C>T p.S7971F | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as COSV67491948; called by muse, mutect2
- MUC16 | c.16679C>T p.S5560F | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as rs1315957079; called by muse, mutect2, varscan2
- MUC16 | c.14801C>T p.S4934F | Missense Mutation (SNP) | VAF 106/346 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.699); catalogued as COSV67460665; called by muse, mutect2, varscan2
- MUC16 | c.14636C>T p.S4879F | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as COSV67495457; called by muse, mutect2, varscan2
- MUC16 | c.11279C>T p.P3760L | Missense Mutation (SNP) | VAF 25/352 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs1461747537; called by muse, mutect2
- MUC16 | c.10772C>T p.S3591F | Missense Mutation (SNP) | VAF 73/324 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as COSV67488870, COSV67492576; called by muse, mutect2, varscan2
- MUC16 | c.9758G>A p.G3253E | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.103); catalogued as COSV67483457; called by muse, mutect2, varscan2
- MUC17 | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 111/384 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.19); catalogued as COSV60280423; called by muse, mutect2, varscan2
- MUSK | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.588); catalogued as rs1171563328, COSV99505292; called by muse, mutect2, varscan2
- MXRA5 | c.3209G>A p.G1070E | Missense Mutation (SNP) | VAF 133/365 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54235560; called by muse, mutect2, varscan2
- MYH7B | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 71/368 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs773714865, COSV53424395; called by muse, mutect2, varscan2
- MYO15A | c.4216G>A p.E1406K | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759810756, CM1310510; called by muse, mutect2, varscan2
- MYO1A | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs766672018; called by muse, mutect2, varscan2
- MYT1L | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs981867392; called by muse, mutect2, varscan2
- NBPF3 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV59060058; called by muse, mutect2, varscan2
- NFX1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV59308651; called by muse, mutect2
- NHSL2 | c.439G>A p.D147N (on ENST00000510661; = p.D513N on NM_001013627.2) | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs780600090; called by muse, mutect2, varscan2
- NOS1 | c.2675G>A p.R892Q | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs1205112398; called by muse, mutect2, varscan2
- NPR1 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 140/328 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs1390048691; called by muse, mutect2, varscan2
- NRXN2 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 166/551 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs267603102, COSV99633606; called by muse, mutect2, varscan2
- NRXN3 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 116/444 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs545455819; called by muse, mutect2, varscan2
- NXF3 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as rs770547688; called by muse, mutect2, varscan2
- OR10G7 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 144/419 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs1480229259, COSV100389941, COSV57866127; called by muse, mutect2, varscan2
- OR1L3 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.162); catalogued as COSV59170636; called by muse, mutect2, varscan2
- OR2M4 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 179/432 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV60708038; called by muse, mutect2, varscan2
- OR4A15 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 96/303 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.173); catalogued as COSV59035543; called by muse, mutect2, varscan2
- OR4A16 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 43/455 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as rs1389734335, COSV59041785; called by muse, mutect2
- OR4D11 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 84/291 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs753126010; called by muse, mutect2, varscan2
- OR51B2 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1439501357, COSV60917799; called by muse, mutect2, varscan2
- OR52E2 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58611731; called by muse, mutect2, varscan2
- OR52I2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 32/486 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV100442861; called by muse, mutect2
- OR52N4 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 100/300 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs776548473, COSV57890322; called by muse, mutect2, varscan2
- OR5H14 | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 65/267 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs753877338, COSV71193761; called by muse, mutect2, varscan2
- OR5H15 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as rs746024358; called by muse, mutect2, varscan2
- OR6N1 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 109/341 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs764943230, COSV58650424; called by muse, mutect2, varscan2
- OR8K5 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.194); catalogued as COSV100537315, COSV100537322; called by muse, mutect2, varscan2
- P2RX5 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); catalogued as rs758894452, COSV56593599; called by muse, mutect2
- PASD1 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV64854936, COSV64856591; called by muse, mutect2, varscan2
- PCDH18 | c.1603C>T p.H535Y | Missense Mutation (SNP) | VAF 100/324 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.811); catalogued as COSV100787063, COSV61267409; called by muse, mutect2, varscan2
- PCLO | c.13564G>A p.E4522K | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs867904886; called by muse, mutect2, varscan2
- PCLO | c.12692C>T p.S4231F | Missense Mutation (SNP) | VAF 122/335 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV61615595; called by muse, mutect2, varscan2
- PCLO | c.5488C>T p.L1830F | Missense Mutation (SNP) | VAF 112/358 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61614858; called by muse, mutect2, varscan2
- PCNX1 | c.5197C>T p.R1733C | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs537998725, COSV53097086; called by muse, mutect2, varscan2
- PDE7B | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 131/261 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs1394629770; called by muse, mutect2, varscan2
- PDE8A | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 91/306 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779086059; called by muse, mutect2, varscan2
- PISD | c.907G>T p.E303* (on ENST00000439502 / NM_001326412.1; = p.E269* on NM_014338.3) | Nonsense Mutation (SNP) | VAF 122/442 reads (28%) | catalogued as COSV56716034; called by mutect2, varscan2
- PKP1 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 44/549 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs772895613; called by muse, mutect2
- PLAAT1 | c.784G>A p.G262S (on ENST00000650797; = p.G157S on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/363 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.646); catalogued as rs1214979700; called by muse, mutect2
- PLEC | c.4306C>T p.P1436S (on ENST00000322810 / NM_201380.4; = p.P1326S on NM_000445.5) | Missense Mutation (SNP) | VAF 107/328 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV59614646; called by muse, mutect2, varscan2
- PLIN5 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 132/397 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs1568247048; called by muse, mutect2, varscan2
- POM121 | c.3035C>T p.P1012L (on ENST00000434423; = p.P747L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs542693697, COSV99988609; called by muse, mutect2
- POTEG | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 41/432 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1370060970, COSV101192803; called by muse, mutect2, varscan2
- PPFIA4 | c.2042C>T p.S681L (on ENST00000447715; = p.S682L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.255); catalogued as rs766716828; called by muse, mutect2
- PPP1CA | c.149C>G p.P50R | Missense Mutation (SNP) | VAF 58/281 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV56702677; called by muse, mutect2, varscan2
- PRKDC | c.2105C>T p.S702F | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV58046325; called by muse, mutect2, varscan2
- PRR23C | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 50/524 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV101356465; called by muse, mutect2
- PSTPIP1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 84/281 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs569030059; called by muse, mutect2, varscan2
- PWWP3B | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 98/370 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs369679742; called by muse, mutect2
- RAD50 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 80/301 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs143802516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RASSF6 | c.299G>A p.R100Q (on ENST00000342081 / NM_201431.2; = p.R68Q on NM_177532.5) | Missense Mutation (SNP) | VAF 70/341 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as rs1302260242, COSV100274920; called by muse, mutect2, varscan2
- RBL1 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV60329729; called by muse, mutect2, varscan2
- RFPL4A | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1394638520, COSV101467264; called by muse, mutect2, varscan2
- RHBG | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 173/480 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs267598074, COSV54801708, COSV99659704; called by muse, mutect2, varscan2
- RIMBP2 | c.951G>A p.W317* | Nonsense Mutation (SNP) | VAF 116/392 reads (30%) | catalogued as COSV55470229; called by muse, mutect2, varscan2
- RNF182 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 84/375 reads (22%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.99); catalogued as COSV70369049; called by muse, mutect2, varscan2
- RNF32 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV100311503; called by muse, mutect2
- ROR2 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 132/290 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs55798732, COSV65217539; called by muse, mutect2, varscan2
- RORB | c.998G>A p.G333E (on ENST00000396204 / NM_001365023.1; = p.G322E on NM_006914.4) | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs267602267, COSV65333261, COSV65340965; called by muse, mutect2, varscan2
- RP1 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 54/184 reads (29%) | catalogued as CM130734, COSV55110264; called by muse, mutect2, varscan2
- RP1 | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as rs267601951; called by muse, mutect2, varscan2
- RPGR | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV58837789; called by muse, mutect2, varscan2
- RPTN | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 23/494 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1242425369; called by muse, mutect2
- RUSF1 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 98/350 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as rs1275380960; called by muse, varscan2
- SCN7A | c.3340G>A p.E1114K | Missense Mutation (SNP) | VAF 79/275 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.094); catalogued as rs375736846; called by muse, mutect2, varscan2
- SEC14L5 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 79/257 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as rs546103563, COSV52039754; called by muse, mutect2, varscan2
- SEC24D | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 112/329 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs866077727; called by muse, mutect2, varscan2
- SERPINA5 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 34/425 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753810309; called by muse, mutect2
- SETD3 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs1455194605; called by muse, mutect2, varscan2
- SGCZ | c.60A>G p.I20M | Missense Mutation (SNP) | VAF 59/272 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV66002621; called by muse, mutect2, varscan2
- SGSM2 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 88/236 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52158313; called by muse, mutect2, varscan2
- SIGLEC6 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 128/357 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV58432721; called by muse, mutect2, varscan2
- SKAP2 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 135/383 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as rs1335708568; called by muse, mutect2, varscan2
- SLC22A1 | c.1537C>T p.L513F | Missense Mutation (SNP) | VAF 104/235 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751407403; called by muse, mutect2, varscan2
- SLC24A1 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 95/387 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs759185268, COSV56053156; called by muse, mutect2, varscan2
- SLC5A1 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 100/354 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV56684520; called by muse, mutect2, varscan2
- SLC9A4 | c.2186G>A p.R729K | Missense Mutation (SNP) | VAF 110/294 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99762567, COSV99762662, COSV99762680; called by muse, mutect2, varscan2
- SPAG16 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.805); catalogued as COSV55984130; called by muse, mutect2, varscan2
- SPATA18 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV54649664; called by muse, mutect2, varscan2
- SPATA19 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 110/318 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs749378141, COSV54482497; called by muse, mutect2, varscan2
- SPRR2F | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 208/699 reads (30%) | PolyPhen benign (0); catalogued as rs764872210; called by muse, mutect2, varscan2
- SREBF1 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 94/470 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.339); catalogued as rs753117423; called by muse, mutect2, varscan2
- SRRT | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 136/429 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53816098; called by muse, mutect2, varscan2
- SSUH2 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs757018233; called by muse, mutect2, varscan2
- SSX1 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 79/279 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs1556935968, COSV65355371; called by muse, mutect2, varscan2
- STAB2 | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 90/287 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.339); catalogued as COSV66335897; called by muse, mutect2
- STEAP4 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 91/253 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.327); catalogued as COSV100112362; called by muse, mutect2, varscan2
- TAF1 | c.4936C>T p.Q1646* (on ENST00000373790 / NM_138923.4; = p.Q1667* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 87/313 reads (28%) | catalogued as COSV99337503; called by muse, mutect2, varscan2
- TECPR2 | c.2460G>T p.E820D | Missense Mutation (SNP) | VAF 25/334 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV63970033, COSV63972356; called by muse, mutect2
- TECPR2 | c.3659G>A p.S1220N | Missense Mutation (SNP) | VAF 79/247 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV63969764; called by muse, mutect2, varscan2
- TEX14 | c.1234C>T p.R412* (on ENST00000240361 / NM_001201457.2; = p.R406* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 101/294 reads (34%) | catalogued as rs753803044, COSV53626935; called by muse, mutect2, varscan2
- TGFB2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 145/451 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65108757; called by muse, mutect2, varscan2
- TGM6 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 90/313 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs147591485, COSV99172455; called by muse, mutect2, varscan2
- THAP3 | c.695G>C p.R232T (on ENST00000054650 / NM_001195753.1; = p.R231T on NM_001195752.1) | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.05); catalogued as rs746083160, COSV50010483; called by muse, mutect2, varscan2
- TMC2 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 138/419 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.067); catalogued as rs753247090, COSV62657219; called by muse, mutect2, varscan2
- TMTC2 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 96/309 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as rs758661382; called by muse, mutect2, varscan2
- TOM1 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs752987703; called by muse, mutect2, varscan2
- TP63 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 34/479 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV53213427; called by muse, mutect2
- TPSD1 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 124/398 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as rs368071110; called by muse, varscan2
- TRA2A | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs200126944, COSV51715601; called by muse, mutect2, varscan2
- TRPM3 | c.2230G>T p.V744L (on ENST00000357533 / NM_001366142.2; = p.V587L on NM_020952.6) | Missense Mutation (SNP) | VAF 106/203 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV62579795; called by muse, mutect2, varscan2
- TSEN54 | c.1285A>G p.T429A | Missense Mutation (SNP) | VAF 106/336 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV51365524; called by muse, mutect2, varscan2
- TTBK1 | c.2921G>A p.G974E | Missense Mutation (SNP) | VAF 217/554 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs766326776, COSV99443538; called by muse, mutect2, varscan2
- TTN | c.59189G>A p.R19730K (on ENST00000591111; = p.R12306K on NM_003319.4) | Missense Mutation (SNP) | VAF 40/134 reads (30%) | PolyPhen benign (0.003); catalogued as COSV60217386; called by muse, mutect2, varscan2
- TTN | c.36719G>A p.R12240Q (on ENST00000591111; = p.R4816Q on NM_003319.4) | Missense Mutation (SNP) | VAF 80/230 reads (35%) | PolyPhen possibly damaging (0.873); catalogued as rs1268138413, COSV59911499; called by muse, mutect2, varscan2
- TTN | c.21725G>A p.G7242E (on ENST00000591111; = p.G6315E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/369 reads (24%) | PolyPhen probably damaging (0.986); catalogued as COSV59915855; called by muse, mutect2, varscan2
- UBQLNL | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 104/325 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as COSV66493054; called by muse, mutect2, varscan2
- UBQLNL | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 126/398 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV66494700; called by muse, mutect2
- UGT2A1 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 94/353 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as rs959283062, COSV54138372, COSV54140551; called by muse, mutect2, varscan2
- UPRT | c.409A>G p.M137V | Missense Mutation (SNP) | VAF 107/361 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs748071556; called by muse, mutect2, varscan2
- UVRAG | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 59/208 reads (28%) | catalogued as rs757063839, COSV62109786; called by muse, mutect2, varscan2
- VCX2 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 143/311 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.803); catalogued as rs1216525562; called by muse, mutect2, varscan2
- VN1R2 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 91/263 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as COSV59038377; called by muse, mutect2, varscan2
- VPREB1 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 102/293 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as rs373127258, COSV56425914; called by muse, mutect2, varscan2
- WDR81 | c.3239C>T p.P1080L (on ENST00000409644 / NM_001163809.2; = p.P29L on NM_152348.4) | Missense Mutation (SNP) | VAF 117/455 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as rs1438566192; called by muse, mutect2, varscan2
- WFDC6 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV100323139; called by muse, mutect2, varscan2
- XDH | c.3037C>T p.P1013S | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV65151225; called by muse, varscan2
- XIRP2 | c.1294G>A p.E432K (on ENST00000628543; = p.E607K on NM_152381.6) | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV54684838; called by muse, mutect2
- ZBED5 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs909784487; called by muse, mutect2
- ZFPM2 | c.2786G>A p.G929E | Missense Mutation (SNP) | VAF 100/333 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as COSV65874707; called by muse, mutect2, varscan2
- ZMYM4 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 99/272 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1318149646, COSV58909410; called by muse, mutect2, varscan2
- ZNF157 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 142/448 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV100998419; called by muse, mutect2, varscan2
- ZNF257 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV71309802; called by muse, mutect2, varscan2
- ZNF26 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs1490351584; called by muse, mutect2, varscan2
- ZNF418 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as rs1421820464; called by muse, mutect2, varscan2
- ZNF560 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 80/345 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs149138221, COSV56867070; called by muse, mutect2, varscan2
- ZNF560 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 68/261 reads (26%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.048); catalogued as COSV56868661; called by muse, mutect2, varscan2
- ZNF662 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60240894; called by muse, mutect2
- ZNF679 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.012); catalogued as COSV99738970; called by muse, mutect2, varscan2
- ZNF708 | c.904C>T p.H302Y | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV63606955; called by muse, mutect2, varscan2
- ZNF835 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 134/436 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1244052590; called by muse, mutect2, varscan2
- ZNF865 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 212/573 reads (37%) | SIFT tolerated (0.46); catalogued as rs1344653284; called by muse, mutect2, varscan2
- ABCD2 | c.2126G>A p.G709E | Missense Mutation (SNP) | VAF 34/390 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.803); called by muse, mutect2
- ABI3BP | c.3196G>A p.G1066R | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAP1 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 85/329 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ACE | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ADGRB3 | c.3817_3818insC p.E1273Afs*3 | Frame Shift Ins (INS) | VAF 47/259 reads (18%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.13567C>T p.Q4523* | Nonsense Mutation (SNP) | VAF 77/286 reads (27%) | called by muse, varscan2
- AHNAK2 | c.6284G>A p.G2095D | Missense Mutation (SNP) | VAF 124/326 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- ANKRD31 | c.4621G>A p.E1541K | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD31 | c.3740C>T p.P1247L | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD31 | c.3739C>T p.P1247S | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANXA6 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARFGEF1 | c.455T>A p.I152K | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ARID3A | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 148/550 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ARIH2 | c.299G>T p.W100L | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1562C>T p.S521L | Missense Mutation (SNP) | VAF 81/310 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARR3 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 120/431 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ARSJ | c.497A>T p.E166V | Missense Mutation (SNP) | VAF 119/324 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ATL2 | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- ATP10D | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 75/260 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP2B2 | c.2995G>A p.E999K (on ENST00000352432; = p.E965K on NM_001683.5) | Missense Mutation (SNP) | VAF 28/434 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- BCL7C | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- BEGAIN | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMF | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 62/205 reads (30%) | called by muse, mutect2, varscan2
- BPTF | c.6286G>A p.V2096I | Missense Mutation (SNP) | VAF 99/288 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- C11orf80 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- C11orf80 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- C1orf112 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.367); called by muse, mutect2
- CADM2 | c.773C>T p.P258L (on ENST00000407528 / NM_001167674.2; = p.P260L on NM_153184.4) | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CAMSAP2 | c.3202C>T p.P1068S (on ENST00000236925 / NM_001297707.2; = p.P1057S on NM_203459.3) | Missense Mutation (SNP) | VAF 78/408 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CAMSAP2 | c.3203C>T p.P1068L (on ENST00000236925 / NM_001297707.2; = p.P1057L on NM_203459.3) | Missense Mutation (SNP) | VAF 78/407 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARF | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CARF | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CARNS1 | c.1039G>C p.G347R | Missense Mutation (SNP) | VAF 108/494 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2
- CCDC114 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 75/249 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CCDC175 | c.1092G>A p.M364I | Missense Mutation (SNP) | VAF 87/247 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCN4 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 49/236 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD248 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.826); called by muse, mutect2
- CD44 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CD93 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 134/419 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, varscan2
- CDK1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CEP126 | c.2845_2845+15del p.X949_splice | Splice Site (DEL) | VAF 36/155 reads (23%) | called by mutect2, pindel, varscan2
- CHMP1A | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 146/444 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHTF18 | c.1948C>G p.Q650E | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, varscan2
- CLEC4F | c.1766A>G p.N589S | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); called by muse, mutect2
- CMYA5 | c.7964G>A p.G2655E | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CNOT10 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CNTNAP3 | c.2540C>T p.P847L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL11A1 | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- COL4A1 | c.4304G>A p.G1435E | Missense Mutation (SNP) | VAF 126/412 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- COL4A5 | c.2114G>A p.G705E | Missense Mutation (SNP) | VAF 14/285 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A6 | c.1408C>A p.P470T | Missense Mutation (SNP) | VAF 72/337 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRB1 | c.3838G>A p.E1280K | Missense Mutation (SNP) | VAF 98/277 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- CRYAB | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 75/224 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CSMD1 | c.10606G>A p.E3536K (on ENST00000520002; = p.E3535K on NM_033225.6) | Missense Mutation (SNP) | VAF 114/415 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CSPG4 | c.1025T>G p.L342R | Missense Mutation (SNP) | VAF 85/388 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CYLD | c.2660T>A p.F887Y | Missense Mutation (SNP) | VAF 99/283 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CYP2B6 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DAPP1 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF8L1 | c.1000A>C p.K334Q | Missense Mutation (SNP) | VAF 71/268 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- DCDC1 | c.4043C>T p.S1348L (on ENST00000597505 / NM_001367979.1; = p.S455L on NM_020869.3) | Missense Mutation (SNP) | VAF 94/309 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DDX60 | c.2674C>T p.H892Y | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DESI2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 14/331 reads (4%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2
- DESI2 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); called by muse, mutect2
- DEUP1 | c.1441A>G p.T481A | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- DFFA | c.8T>G p.V3G | Missense Mutation (SNP) | VAF 53/267 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DLEC1 | c.3989C>T p.P1330L | Missense Mutation (SNP) | VAF 130/399 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DNAH9 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 107/327 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DNASE1L3 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 107/355 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSP | c.2000G>A p.W667* | Nonsense Mutation (SNP) | VAF 103/448 reads (23%) | called by muse, mutect2, varscan2
- DSP | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DZANK1 | c.1849G>A p.G617R (on ENST00000262547 / NM_001099407.1; = p.G424R on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/368 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EEF1AKNMT | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 104/279 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- EFR3B | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 32/276 reads (12%) | called by muse, mutect2, varscan2
- ELFN1 | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 134/499 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- EML5 | c.4617C>A p.F1539L (on ENST00000380664; = p.F1547L on NM_183387.3) | Missense Mutation (SNP) | VAF 62/309 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ENPEP | c.1227G>A p.W409* | Nonsense Mutation (SNP) | VAF 75/265 reads (28%) | called by muse, mutect2, varscan2
- ERN2 | c.1227dup p.L410Tfs*28 | Frame Shift Ins (INS) | VAF 77/255 reads (30%) | called by mutect2, pindel, varscan2
- EXOC8 | c.1630C>T p.H544Y | Missense Mutation (SNP) | VAF 151/346 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FAM110C | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FAM81A | c.395T>G p.L132R | Missense Mutation (SNP) | VAF 26/299 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAP | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 38/121 reads (31%) | called by muse, mutect2, varscan2
- FAR1 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- FBXO40 | c.763C>T p.H255Y | Missense Mutation (SNP) | VAF 77/286 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGF2 | c.623A>G p.K208R | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- FMN2 | c.2543C>T p.A848V | Missense Mutation (SNP) | VAF 145/441 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FREM1 | c.4130G>A p.R1377K | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- FRG2C | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.439); called by muse, mutect2
- FZD9 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 16/401 reads (4%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.897); called by muse, mutect2
- GALNT11 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GFRA4 | c.871C>T p.P291S (on ENST00000319242 / NM_145762.3; = p.P261S on NM_022139.4) | Missense Mutation (SNP) | VAF 116/346 reads (34%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GLI2 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 127/408 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GNPTG | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 98/298 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GPR171 | c.843T>G p.D281E | Missense Mutation (SNP) | VAF 80/315 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPRIN1 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 91/399 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- GRP | c.44T>A p.L15H | Missense Mutation (SNP) | VAF 122/413 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HAVCR2 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 64/309 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCN1 | c.1417A>G p.M473V | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2
- HDLBP | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 105/329 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- HECTD4 | c.5609C>T p.P1870L | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HOXA2 | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 90/312 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HPX | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 148/423 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HRH3 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 103/321 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- HYDIN | c.10337T>C p.I3446T | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.029); called by muse, mutect2
- IBSP | c.49T>A p.F17I | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- IGSF10 | c.7379C>T p.P2460L | Missense Mutation (SNP) | VAF 102/305 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- INPP5B | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 104/323 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ISCU | c.476C>T p.P159L (on ENST00000311893 / NM_213595.4; = p.P134L on NM_014301.4) | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- IWS1 | c.1964G>A p.S655N | Missense Mutation (SNP) | VAF 61/280 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- JUP | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- KAZN | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 120/353 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCND1 | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 130/429 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCTD17 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 54/276 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- KDM7A | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 131/340 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- KDR | c.3787G>A p.V1263I | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF26B | c.1199A>G p.K400R | Missense Mutation (SNP) | VAF 144/458 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- KIF3A | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 78/204 reads (38%) | called by muse, mutect2, varscan2
- KRTAP5-10 | c.496T>A p.C166S | Missense Mutation (SNP) | VAF 55/589 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.187); called by muse, mutect2
- KSR2 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- LETM2 | c.406G>A p.G136R (on ENST00000379957 / NM_001286819.2; = p.G89R on NM_144652.3) | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LETM2 | c.407G>T p.G136V (on ENST00000379957 / NM_001286819.2; = p.G89V on NM_144652.3) | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGALS9 | c.640C>T p.P214S (on ENST00000395473 / NM_009587.3; = p.P182S on NM_002308.4) | Missense Mutation (SNP) | VAF 112/360 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- LOXHD1 | c.2219C>T p.T740I | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- LRP1B | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- LSP1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 91/385 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MAGEB16 | c.968G>A p.R323K | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- MAGEL2 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 182/719 reads (25%) | SIFT tolerated, low confidence (0.11); called by muse, mutect2, varscan2
- MAP2K2 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 138/430 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K7 | c.1373C>T p.S458F (on ENST00000369329 / NM_145331.3; = p.S431F on NM_003188.4) | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- MARCHF11 | c.630G>A p.W210* | Nonsense Mutation (SNP) | VAF 98/351 reads (28%) | called by muse, mutect2, varscan2
- MARCHF6 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- MARCHF6 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 73/319 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- MEGF10 | c.3293C>T p.P1098L | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, varscan2
- MEGF11 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, varscan2
- MFSD6L | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 128/358 reads (36%) | called by muse, mutect2, varscan2
- MINDY4B | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- MKKS | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- MMP24 | c.1328T>C p.F443S | Missense Mutation (SNP) | VAF 71/238 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MOGAT1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- MOK | c.145_151del p.R49Sfs*4 | Frame Shift Del (DEL) | VAF 44/218 reads (20%) | called by mutect2, pindel, varscan2
- MPO | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MRGPRE | c.389G>A p.W130* | Nonsense Mutation (SNP) | VAF 111/490 reads (23%) | called by muse, mutect2, varscan2
- MTA3 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 84/266 reads (32%) | called by muse, mutect2, varscan2
- MTHFS | c.22A>C p.S8R | Missense Mutation (SNP) | VAF 13/347 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2
- MUC12 | c.13289T>C p.L4430S (on ENST00000379442; = p.L4287S on NM_001164462.1) | Missense Mutation (SNP) | VAF 52/572 reads (9%) | SIFT tolerated (0.12); called by muse, mutect2
- MUC13 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 92/282 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- MUC16 | c.15026G>A p.G5009E | Missense Mutation (SNP) | VAF 66/324 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- MUC16 | c.13357C>T p.P4453S | Missense Mutation (SNP) | VAF 109/342 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- MUC21 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 158/926 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- MXRA5 | c.4234G>A p.E1412K | Missense Mutation (SNP) | VAF 107/321 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MYO15A | c.7695C>G p.N2565K | Missense Mutation (SNP) | VAF 118/343 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO7A | c.4205C>T p.S1402F | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NEB | c.5934G>A p.M1978I | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NEBL | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 51/162 reads (31%) | called by muse, mutect2, varscan2
- NFIA | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NLRP10 | c.44G>A p.W15* | Nonsense Mutation (SNP) | VAF 141/406 reads (35%) | called by muse, mutect2, varscan2
- NLRP2 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 59/502 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOS1 | c.3252G>A p.W1084* | Nonsense Mutation (SNP) | VAF 48/217 reads (22%) | called by muse, mutect2, varscan2
- NOS1 | c.3251G>T p.W1084L | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOSIP | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- NRAP | c.2341C>T p.L781F (on ENST00000359988 / NM_001322945.2; = p.L746F on NM_006175.4) | Missense Mutation (SNP) | VAF 91/212 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- NUP210 | c.3631C>T p.H1211Y | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- OBSCN | c.19499C>A p.P6500H | Missense Mutation (SNP) | VAF 98/539 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OPRPN | c.184T>C p.S62P | Missense Mutation (SNP) | VAF 117/376 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1J1 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.913); called by muse, mutect2
- OR4E1 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- OR4K2 | c.383A>G p.K128R | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- OR4K3 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 61/317 reads (19%) | called by muse, mutect2, varscan2
- OR4K3 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 69/473 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- OR52E1 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR5A2 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR6K2 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 184/464 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6K6 | c.570G>A p.W190* (on ENST00000368144; = p.W166* on NM_001005184.1) | Nonsense Mutation (SNP) | VAF 207/484 reads (43%) | called by muse, mutect2, varscan2
- OR8A1 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 118/357 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- OSBPL8 | c.2578C>G p.P860A | Missense Mutation (SNP) | VAF 25/323 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- P3H2 | c.1481G>C p.R494T | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- PAPPA2 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 177/422 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PAPPA2 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 116/420 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDHB1 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 72/329 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- PCNT | c.6679C>T p.P2227S | Missense Mutation (SNP) | VAF 69/383 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCSK6 | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 85/278 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PDE12 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PDE12 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 61/302 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE1A | c.1022A>T p.N341I | Missense Mutation (SNP) | VAF 69/214 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDYN | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 71/238 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PGD | c.1404C>A p.N468K | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PIEZO2 | c.1592G>A p.W531* | Nonsense Mutation (SNP) | VAF 69/276 reads (25%) | called by muse, mutect2, varscan2
- PIGN | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PIK3C2A | c.1982A>T p.N661I | Missense Mutation (SNP) | VAF 94/337 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PIK3CG | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PITPNM3 | c.1806A>T p.E602D | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- PLA2G4D | c.2279C>T p.T760I | Missense Mutation (SNP) | VAF 120/352 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PLA2G4F | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 97/338 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLD4 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLSCR3 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 29/335 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- PPP1R9A | c.3175C>T p.Q1059* | Nonsense Mutation (SNP) | VAF 54/287 reads (19%) | called by muse, mutect2, varscan2
- PPP6C | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 79/176 reads (45%) | called by muse, mutect2, varscan2
- PQBP1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2
- PTPRB | c.1771C>T p.H591Y | Missense Mutation (SNP) | VAF 103/349 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PTPRQ | c.2693C>T p.S898F (on ENST00000616559; = p.S856F on NM_001145026.2) | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PWWP2A | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 122/423 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, varscan2
- PYGM | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 68/245 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- PZP | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 72/233 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RANBP6 | c.2720C>T p.S907L | Missense Mutation (SNP) | VAF 117/220 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- RASIP1 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 108/424 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RBM15B | c.691A>G p.S231G | Missense Mutation (SNP) | VAF 129/391 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RECQL5 | c.2098C>A p.L700I | Missense Mutation (SNP) | VAF 130/406 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RESF1 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ROGDI | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- RP1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- RPS6KA1 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RTKN | c.401A>T p.D134V (on ENST00000272430 / NM_001015055.2; = p.D121V on NM_033046.2) | Missense Mutation (SNP) | VAF 112/320 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR1 | c.458C>A p.S153Y | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SBF2 | c.5003C>T p.T1668I | Missense Mutation (SNP) | VAF 99/329 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCNN1G | c.1628T>A p.V543D | Missense Mutation (SNP) | VAF 108/380 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- SELP | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 187/517 reads (36%) | called by muse, mutect2, varscan2
- SEMA4F | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 92/345 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- SEMA5A | c.2236G>A p.G746R | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SETX | c.2692C>T p.P898S | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIGLEC7 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- SIPA1L2 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 191/465 reads (41%) | called by muse, mutect2, varscan2
- SLC17A1 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 141/326 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SLC1A7 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 119/374 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC26A9 | c.2264G>A p.G755E | Missense Mutation (SNP) | VAF 32/466 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- SLC2A12 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 104/179 reads (58%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC4A2 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 126/331 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SLC6A11 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC6A4 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SMIM9 | c.121G>T p.G41* | Nonsense Mutation (SNP) | VAF 95/297 reads (32%) | called by muse, mutect2, varscan2
- SMPX | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 88/392 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPEG | c.4948G>A p.A1650T | Missense Mutation (SNP) | VAF 31/568 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- STAB2 | c.3688C>T p.L1230F | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- STK31 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- TAS1R1 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 107/375 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TASOR | c.2474A>T p.Y825F (on ENST00000355628 / NM_001365636.2; = p.Y429F on NM_015224.3) | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- TECPR2 | c.3911C>T p.T1304I | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- TEP1 | c.6092A>G p.D2031G | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2
- TEX13C | c.2939G>A p.R980K | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TEX37 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 17/355 reads (5%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.003); called by muse, mutect2
- THOC2 | c.1113C>A p.Y371* | Nonsense Mutation (SNP) | VAF 104/408 reads (25%) | called by muse, mutect2, varscan2
- THRAP3 | c.1274T>A p.F425Y | Missense Mutation (SNP) | VAF 81/315 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- TIPRL | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- TMEM108 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 133/374 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TMEM131L | c.4075G>A p.E1359K | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- TMEM30B | c.758G>A p.W253* | Nonsense Mutation (SNP) | VAF 48/397 reads (12%) | called by muse, mutect2, varscan2
- TMEM61 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 93/335 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TOX2 | c.911C>T p.S304F (on ENST00000358131 / NM_001098798.2; = p.S280F on NM_032883.3) | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TPR | c.6643C>T p.P2215S | Missense Mutation (SNP) | VAF 141/371 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TTC27 | c.2131del p.I711Sfs*55 | Frame Shift Del (DEL) | VAF 63/362 reads (17%) | called by mutect2, pindel, varscan2
- UBE2D2 | c.121-1G>A p.X41_splice | Splice Site (SNP) | VAF 27/316 reads (9%) | called by muse, mutect2
- UPF2 | c.1802G>A p.R601K | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- USP29 | c.1739C>T p.S580L | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USP32 | c.3905C>T p.P1302L | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); called by muse, mutect2
- VWA5A | c.1631C>T p.T544I | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- VWA5A | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR35 | c.3258A>T p.K1086N (on ENST00000345530 / NM_001006657.2; = p.K1075N on NM_020779.4) | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- WDR49 | c.733C>T p.L245F (on ENST00000308378 / NM_001366158.1; = p.L586F on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- WHAMM | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- WT1 | c.679T>C p.F227L | Missense Mutation (SNP) | VAF 83/269 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZBED5 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- ZC3H11A | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 103/288 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZC3H4 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 97/328 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZFP64 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZFYVE9 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 79/315 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZMAT4 | c.541C>A p.Q181K | Missense Mutation (SNP) | VAF 95/280 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ZMYM3 | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF121 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 79/307 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF385B | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 95/279 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ZNF469 | c.8506C>T p.P2836S (on ENST00000437464; = p.P2864S on NM_001367624.2) | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF574 | c.1844C>T p.S615F | Missense Mutation (SNP) | VAF 132/407 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ZNF750 | c.1808G>A p.S603N | Missense Mutation (SNP) | VAF 164/531 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF761 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ZNF831 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 115/423 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- AADACL3 | c.222C>T p.F74= | Silent (SNP) | VAF 103/322 reads (32%) | called by muse, mutect2, varscan2
- AC244197.3 | c.726C>T p.L242= | Silent (SNP) | VAF 140/372 reads (38%) | catalogued as COSV61712823; called by muse, mutect2, varscan2
- ACY3 | c.336C>T p.V112= | Silent (SNP) | VAF 29/414 reads (7%) | catalogued as rs755697600; called by muse, mutect2
- ADAMTS12 | c.693C>T p.N231= | Silent (SNP) | VAF 93/289 reads (32%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.1473G>A p.Q491= | Silent (SNP) | VAF 55/171 reads (32%) | catalogued as rs773927392, COSV64601778; called by muse, mutect2, varscan2
- ADCY5 | c.3561G>A p.G1187= | Silent (SNP) | VAF 68/231 reads (29%) | called by muse, varscan2
- ADNP | c.1353C>T p.I451= | Silent (SNP) | VAF 69/193 reads (36%) | called by muse, mutect2, varscan2
- ADPRM | c.711G>A p.V237= | Silent (SNP) | VAF 31/159 reads (19%) | called by muse, mutect2, varscan2
- AHNAK | c.15321T>C p.P5107= | Silent (SNP) | VAF 104/340 reads (31%) | called by muse, mutect2, varscan2
- AKR1C3 | c.486C>T p.S162= | Silent (SNP) | VAF 89/201 reads (44%) | called by muse, mutect2, varscan2
- AMMECR1L | c.591C>T p.L197= | Silent (SNP) | VAF 26/364 reads (7%) | called by muse, mutect2
- AMOTL2 | c.270C>T p.T90= | Silent (SNP) | VAF 44/465 reads (9%) | catalogued as rs764484061, COSV99998272; called by muse, mutect2
- AP3B2 | c.1884C>T p.S628= | Silent (SNP) | VAF 116/366 reads (32%) | called by muse, mutect2, varscan2
- AQP9 | c.108G>A p.L36= | Silent (SNP) | VAF 15/199 reads (8%) | catalogued as rs1251246026; called by muse, mutect2
- ARAF | c.798G>A p.G266= | Silent (SNP) | VAF 170/552 reads (31%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.2220C>T p.T740= (on ENST00000359920 / NM_001130955.2; = p.T636= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 124/376 reads (33%) | catalogued as rs779951642; called by muse, mutect2, varscan2
- ARHGEF7 | c.615C>T p.F205= (on ENST00000375741 / NM_001113511.2; = p.F27= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 114/378 reads (30%) | called by muse, mutect2, varscan2
- ARSH | c.948C>T p.T316= | Silent (SNP) | VAF 121/347 reads (35%) | catalogued as COSV66964009; called by muse, mutect2, varscan2
- BMF | c.276C>T p.P92= | Silent (SNP) | VAF 66/221 reads (30%) | called by muse, varscan2
- BTBD11 | c.561C>T p.S187= | Silent (SNP) | VAF 147/449 reads (33%) | catalogued as rs760174069; called by muse, mutect2, varscan2
- BTNL3 | c.1167C>T p.F389= | Silent (SNP) | VAF 65/241 reads (27%) | called by muse, mutect2
- C12orf56 | c.369G>A p.R123= | Silent (SNP) | VAF 66/192 reads (34%) | catalogued as COSV61486328; called by muse, mutect2, varscan2
- CACNA1C | c.1752C>T p.F584= | Silent (SNP) | VAF 25/402 reads (6%) | catalogued as rs886043677, COSV59694388; ClinVar: uncertain significance; called by muse, mutect2
- CACNA1H | c.1845G>A p.T615= | Silent (SNP) | VAF 117/405 reads (29%) | catalogued as rs776887979, COSV61989774; called by muse, mutect2, varscan2
- CAPN5 | c.489C>T p.F163= (on ENST00000456580; = p.F123= on NM_004055.5) | Silent (SNP) | VAF 134/441 reads (30%) | catalogued as COSV53686937; called by muse, mutect2, varscan2
- CBLC | c.639C>T p.V213= | Silent (SNP) | VAF 67/280 reads (24%) | catalogued as COSV54322881; called by muse, mutect2, varscan2
- CCDC168 | c.13977C>T p.P4659= | Silent (SNP) | VAF 101/331 reads (31%) | called by muse, mutect2, varscan2
- CCIN | c.930C>A p.L310= | Silent (SNP) | VAF 110/239 reads (46%) | called by muse, mutect2, varscan2
- CD180 | c.498C>T p.F166= | Silent (SNP) | VAF 99/334 reads (30%) | called by muse, mutect2, varscan2
- CFTR | c.1485C>T p.S495= | Silent (SNP) | VAF 111/338 reads (33%) | called by muse, mutect2, varscan2
- CKM | c.924C>T p.F308= | Silent (SNP) | VAF 82/354 reads (23%) | catalogued as rs1254595507, COSV53469235; called by muse, mutect2, varscan2
- CLSPN | c.1302C>T p.F434= | Silent (SNP) | VAF 71/307 reads (23%) | catalogued as COSV52051352; called by muse, mutect2, varscan2
- CMYA5 | c.10203C>T p.I3401= | Silent (SNP) | VAF 89/300 reads (30%) | catalogued as COSV71408149; called by muse, mutect2, varscan2
- COL28A1 | c.2964C>T p.L988= | Silent (SNP) | VAF 60/323 reads (19%) | catalogued as rs367640726; called by muse, mutect2, varscan2
- COL5A1 | c.1464C>T p.P488= | Silent (SNP) | VAF 84/188 reads (45%) | catalogued as COSV65675979; called by muse, mutect2, varscan2
- CORIN | c.2013C>T p.D671= | Silent (SNP) | VAF 91/299 reads (30%) | called by muse, mutect2, varscan2
- CPAMD8 | c.1185C>T p.Y395= (on ENST00000651564; = p.Y348= on NM_015692.5) | Silent (SNP) | VAF 59/274 reads (22%) | called by muse, mutect2, varscan2
- CXCR1 | c.51C>T p.F17= | Silent (SNP) | VAF 98/335 reads (29%) | catalogued as rs1490609886, COSV99826275; called by muse, mutect2, varscan2
- CYP1A2 | c.876G>A p.K292= | Silent (SNP) | VAF 129/387 reads (33%) | called by muse, mutect2, varscan2
- CYP26B1 | c.1060C>T p.L354= | Silent (SNP) | VAF 82/428 reads (19%) | called by muse, mutect2, varscan2
- CYP26B1 | c.1059C>T p.Y353= | Silent (SNP) | VAF 82/430 reads (19%) | called by muse, mutect2, varscan2
- CYP4F11 | c.714G>A p.Q238= | Silent (SNP) | VAF 65/281 reads (23%) | catalogued as COSV56129124; called by muse, mutect2, varscan2
- DAG1 | c.2247C>T p.V749= | Silent (SNP) | VAF 32/400 reads (8%) | called by muse, mutect2
- DCN | c.411C>T p.S137= | Silent (SNP) | VAF 54/252 reads (21%) | catalogued as rs765079976; called by muse, mutect2, varscan2
- DDO | c.99C>T p.I33= | Silent (SNP) | VAF 90/225 reads (40%) | called by muse, mutect2, varscan2
- DIAPH1 | c.648G>A p.E216= | Silent (SNP) | VAF 91/285 reads (32%) | catalogued as COSV53879955; called by muse, mutect2, varscan2
- DLGAP1 | c.174G>A p.V58= | Silent (SNP) | VAF 171/525 reads (33%) | catalogued as rs752471224; called by muse, mutect2, varscan2
- DLGAP2 | c.798C>T p.H266= | Silent (SNP) | VAF 214/662 reads (32%) | called by muse, mutect2, varscan2
- DNAH14 | c.8757G>A p.K2919= (on ENST00000445597; = p.K3722= on NM_001367479.1) | Silent (SNP) | VAF 152/363 reads (42%) | called by muse, mutect2, varscan2
- DOLPP1 | c.186C>T p.F62= | Silent (SNP) | VAF 67/190 reads (35%) | catalogued as COSV59910516; called by muse, mutect2, varscan2
- DSG1 | c.2907G>A p.G969= | Silent (SNP) | VAF 44/444 reads (10%) | catalogued as COSV57133082, COSV99935605; called by muse, mutect2
- EFR3B | c.1122C>T p.F374= | Silent (SNP) | VAF 32/281 reads (11%) | catalogued as rs887033584; called by muse, mutect2, varscan2
- EHD2 | c.840C>G p.R280= | Silent (SNP) | VAF 71/433 reads (16%) | called by muse, mutect2, varscan2
- EHD3 | c.762C>T p.I254= | Silent (SNP) | VAF 52/302 reads (17%) | catalogued as COSV59031936; called by muse, mutect2, varscan2
- EIF4E1B | c.456C>T p.D152= | Silent (SNP) | VAF 95/295 reads (32%) | called by muse, mutect2, varscan2
- EMID1 | c.720G>A p.V240= | Silent (SNP) | VAF 91/480 reads (19%) | called by muse, mutect2, varscan2
- FABP7 | c.201G>A p.L67= | Silent (SNP) | VAF 73/191 reads (38%) | catalogued as COSV62956661, COSV62956976; called by muse, mutect2, varscan2
- FAM160A1 | c.1866G>A p.K622= | Silent (SNP) | VAF 71/291 reads (24%) | called by muse, mutect2, varscan2
- FAM160B2 | c.1248C>T p.L416= | Silent (SNP) | VAF 135/438 reads (31%) | called by muse, mutect2, varscan2
- FAM47A | c.2352C>T p.I784= | Silent (SNP) | VAF 75/220 reads (34%) | catalogued as rs267606440, COSV60494156; called by muse, mutect2, varscan2
- FAT3 | c.12828C>T p.A4276= | Silent (SNP) | VAF 96/323 reads (30%) | called by muse, mutect2, varscan2
- FFAR1 | c.255C>T p.A85= | Silent (SNP) | VAF 96/408 reads (24%) | catalogued as COSV50049881; called by muse, varscan2
- FGFRL1 | c.1233C>T p.A411= | Silent (SNP) | VAF 46/571 reads (8%) | called by muse, mutect2
- GABRA1 | c.294G>A p.K98= | Silent (SNP) | VAF 49/198 reads (25%) | called by muse, mutect2, varscan2
- GAS2L2 | c.165C>T p.F55= | Silent (SNP) | VAF 119/424 reads (28%) | catalogued as rs188247631; called by muse, mutect2, varscan2
- GGA1 | c.783C>T p.P261= | Silent (SNP) | VAF 75/290 reads (26%) | catalogued as rs1260009904; called by muse, mutect2, varscan2
- GJC1 | c.243C>T p.I81= | Silent (SNP) | VAF 81/368 reads (22%) | catalogued as rs1246963430; called by muse, mutect2, varscan2
- GMPR2 | c.702A>T p.A234= (on ENST00000355299 / NM_001351022.2; = p.A252= on NM_016576.5) | Silent (SNP) | VAF 34/189 reads (18%) | called by muse, mutect2, varscan2
- GPAA1 | c.39C>T p.L13= | Silent (SNP) | VAF 86/373 reads (23%) | called by muse, mutect2, varscan2
- GPC6 | c.1260G>A p.E420= | Silent (SNP) | VAF 97/328 reads (30%) | catalogued as rs746908216; called by muse, mutect2
- GPS1 | c.264G>A p.V88= | Silent (SNP) | VAF 94/313 reads (30%) | called by muse, mutect2, varscan2
- GPSM2 | c.372T>C p.C124= | Silent (SNP) | VAF 75/261 reads (29%) | called by muse, mutect2, varscan2
- GREB1 | c.3231C>T p.P1077= | Silent (SNP) | VAF 87/327 reads (27%) | catalogued as COSV99303780; called by muse, mutect2, varscan2
- GRM7 | c.987C>T p.I329= | Silent (SNP) | VAF 95/291 reads (33%) | catalogued as rs373414573; called by muse, mutect2, varscan2
- H3C4 | c.240G>A p.K80= | Silent (SNP) | VAF 108/312 reads (35%) | catalogued as rs752760118, COSV61911589; called by muse, mutect2, varscan2
- HCK | c.1005C>T p.F335= | Silent (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- HEPH | c.2811G>A p.E937= (on ENST00000343002; = p.E670= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 120/384 reads (31%) | called by muse, mutect2, varscan2
- HMGB3 | c.537G>A p.K179= | Silent (SNP) | VAF 87/323 reads (27%) | catalogued as COSV100308678; called by muse, mutect2, varscan2
- HMGB4 | c.444C>T p.L148= | Silent (SNP) | VAF 109/327 reads (33%) | called by muse, mutect2, varscan2
- HOMER3 | c.1027C>T p.L343= | Silent (SNP) | VAF 51/617 reads (8%) | called by muse, mutect2
- HPSE2 | c.876C>T p.P292= | Silent (SNP) | VAF 115/217 reads (53%) | called by muse, mutect2, varscan2
- HS3ST4 | c.762G>A p.G254= | Silent (SNP) | VAF 71/232 reads (31%) | called by muse, mutect2, varscan2
- HUWE1 | c.3291C>G p.A1097= | Silent (SNP) | VAF 112/426 reads (26%) | catalogued as COSV53352090; called by muse, mutect2, varscan2
- HYDIN | c.2098C>T p.L700= | Silent (SNP) | VAF 63/201 reads (31%) | called by muse, mutect2, varscan2
- IGSF9B | c.2127C>T p.F709= | Silent (SNP) | VAF 65/261 reads (25%) | called by muse, mutect2, varscan2
- IL31 | c.189C>T p.L63= | Silent (SNP) | VAF 91/288 reads (32%) | catalogued as rs757429634; called by muse, mutect2
- IL32 | c.657G>A p.K219= (on ENST00000396890 / NM_001308078.4; = p.K173= on NM_004221.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/383 reads (14%) | catalogued as rs772552901; called by muse, mutect2
- IQSEC2 | c.1179C>T p.S393= (on ENST00000642864 / NM_001111125.3; = p.S188= on NM_015075.2) | Silent (SNP) | VAF 110/528 reads (21%) | catalogued as COSV64723888; called by muse, mutect2, varscan2
- ITGAL | c.1848G>A p.V616= | Silent (SNP) | VAF 16/291 reads (5%) | catalogued as rs1567477544; called by muse, mutect2
- ITIH6 | c.3783C>T p.C1261= | Silent (SNP) | VAF 132/395 reads (33%) | called by muse, mutect2, varscan2
- JDP2 | c.261C>T p.A87= | Silent (SNP) | VAF 32/386 reads (8%) | called by muse, mutect2
- KCND3 | c.1035C>T p.G345= | Silent (SNP) | VAF 70/217 reads (32%) | catalogued as rs1403938903; called by muse, mutect2, varscan2
- KCNK13 | c.690C>T p.F230= | Silent (SNP) | VAF 84/341 reads (25%) | called by muse, mutect2, varscan2
- KIAA1217 | c.1815G>A p.R605= | Silent (SNP) | VAF 82/181 reads (45%) | catalogued as COSV56821823; called by muse, mutect2, varscan2
- KLHL34 | c.1326G>A p.S442= | Silent (SNP) | VAF 56/596 reads (9%) | called by muse, mutect2
- KMT2D | c.14994G>A p.K4998= | Silent (SNP) | VAF 80/399 reads (20%) | catalogued as COSV99981292; called by muse, mutect2, varscan2
- KRT3 | c.816G>A p.L272= | Silent (SNP) | VAF 94/375 reads (25%) | called by muse, mutect2, varscan2
- KRT36 | c.378G>A p.Q126= | Silent (SNP) | VAF 97/319 reads (30%) | called by muse, mutect2, varscan2
- KRT37 | c.670C>T p.L224= | Silent (SNP) | VAF 157/507 reads (31%) | called by muse, mutect2, varscan2
- LAMA5 | c.6522C>T p.L2174= | Silent (SNP) | VAF 29/354 reads (8%) | called by muse, mutect2
- LAMB3 | c.597G>A p.G199= | Silent (SNP) | VAF 134/408 reads (33%) | called by muse, mutect2, varscan2
- LANCL3 | c.360C>T p.F120= | Silent (SNP) | VAF 136/420 reads (32%) | catalogued as rs1556415708; called by muse, mutect2, varscan2
- LILRA2 | c.24G>A p.L8= | Silent (SNP) | VAF 114/637 reads (18%) | catalogued as COSV52188164, COSV52191564; called by muse, mutect2, varscan2
- LILRA4 | c.675C>T p.S225= | Silent (SNP) | VAF 132/402 reads (33%) | called by muse, mutect2, varscan2
- LLGL2 | c.1485C>T p.S495= | Silent (SNP) | VAF 76/231 reads (33%) | called by muse, mutect2, varscan2
- LPIN3 | c.207C>T p.L69= | Silent (SNP) | VAF 81/282 reads (29%) | catalogued as rs756547433, COSV64718428; called by muse, mutect2, varscan2
- LRRC15 | c.357C>T p.G119= | Silent (SNP) | VAF 184/396 reads (46%) | called by muse, mutect2, varscan2
- LRRC36 | c.1794C>T p.V598= | Silent (SNP) | VAF 26/270 reads (10%) | called by muse, mutect2
- LTBP4 | c.4524C>T p.S1508= (on ENST00000308370 / NM_001042544.1; = p.S1471= on NM_003573.2) | Silent (SNP) | VAF 110/393 reads (28%) | called by muse, mutect2, varscan2
- LUM | c.660C>T p.I220= | Silent (SNP) | VAF 86/295 reads (29%) | called by muse, mutect2, varscan2
- MAFA | c.669G>A p.L223= | Silent (SNP) | VAF 90/433 reads (21%) | called by muse, varscan2
- MAGEB5 | c.798G>A p.A266= | Silent (SNP) | VAF 120/349 reads (34%) | catalogued as rs189463527; called by muse, mutect2, varscan2
- MAP4K1 | c.285G>A p.G95= | Silent (SNP) | VAF 71/292 reads (24%) | called by muse, mutect2, varscan2
- MARCO | c.114G>A p.R38= | Silent (SNP) | VAF 72/248 reads (29%) | catalogued as rs1392081299, COSV59055942; called by muse, mutect2, varscan2
- MARF1 | c.4887C>T p.V1629= | Silent (SNP) | VAF 42/560 reads (8%) | called by muse, mutect2
- MAST4 | c.5850G>A p.L1950= (on ENST00000403625 / NM_001164664.2; = p.L1761= on NM_015183.3) | Silent (SNP) | VAF 66/321 reads (21%) | called by muse, mutect2, varscan2
- MATN3 | c.337C>T p.L113= | Silent (SNP) | VAF 112/339 reads (33%) | called by muse, mutect2, varscan2
- MCTP2 | c.2385C>T p.F795= | Silent (SNP) | VAF 25/215 reads (12%) | catalogued as COSV63295371; called by muse, mutect2, varscan2
- MEFV | c.1953C>T p.G651= | Silent (SNP) | VAF 123/374 reads (33%) | called by muse, mutect2, varscan2
- MEP1A | c.2064G>A p.V688= | Silent (SNP) | VAF 66/295 reads (22%) | called by muse, mutect2, varscan2
- MFSD2A | c.816C>T p.I272= (on ENST00000372809 / NM_001136493.3; = p.I259= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 75/221 reads (34%) | catalogued as rs965560729; called by muse, mutect2, varscan2
- MFSD8 | c.1035C>T p.I345= | Silent (SNP) | VAF 97/310 reads (31%) | catalogued as rs141422574; ClinVar: likely benign; called by muse, mutect2, varscan2
- MICAL2 | c.3165C>T p.H1055= | Silent (SNP) | VAF 65/246 reads (26%) | called by muse, mutect2, varscan2
- MOGAT2 | c.138C>T p.F46= | Silent (SNP) | VAF 119/364 reads (33%) | called by muse, mutect2, varscan2
- MTCL1 | c.5013G>A p.G1671= (on ENST00000306329 / NM_001378206.1; = p.G1352= on NM_015210.4) | Silent (SNP) | VAF 129/422 reads (31%) | catalogued as rs1321810471; called by muse, mutect2, varscan2
- MTMR14 | c.738C>T p.S246= | Silent (SNP) | VAF 79/265 reads (30%) | called by muse, mutect2, varscan2
- MUC12 | c.13288T>C p.L4430= (on ENST00000379442; = p.L4287= on NM_001164462.1) | Silent (SNP) | VAF 52/585 reads (9%) | catalogued as rs1466877309; called by muse, mutect2
- MYBPC2 | c.522G>A p.K174= | Silent (SNP) | VAF 19/281 reads (7%) | catalogued as rs1207523719, COSV63094816; called by muse, mutect2
- MYH7B | c.933C>T p.L311= | Silent (SNP) | VAF 53/268 reads (20%) | catalogued as rs763246752; called by muse, mutect2, varscan2
- MYH7B | c.1779G>A p.R593= | Silent (SNP) | VAF 71/373 reads (19%) | catalogued as COSV53416499; called by muse, mutect2, varscan2
- MYO18B | c.3438G>A p.L1146= | Silent (SNP) | VAF 121/452 reads (27%) | called by muse, mutect2, varscan2
- MYO18B | c.3807C>T p.F1269= | Silent (SNP) | VAF 76/274 reads (28%) | called by muse, mutect2, varscan2
- NCOR2 | c.6768C>T p.S2256= | Silent (SNP) | VAF 75/244 reads (31%) | called by muse, mutect2, varscan2
- NIBAN1 | c.2334C>T p.P778= | Silent (SNP) | VAF 199/579 reads (34%) | catalogued as rs750801506, COSV100836238; called by muse, mutect2, varscan2
- NLK | c.882C>T p.S294= | Silent (SNP) | VAF 26/334 reads (8%) | called by muse, mutect2
- NLRP2 | c.1092G>A p.R364= | Silent (SNP) | VAF 127/492 reads (26%) | called by muse, mutect2, varscan2
- NLRP8 | c.1687C>T p.L563= | Silent (SNP) | VAF 74/299 reads (25%) | called by muse, mutect2, varscan2
- NR0B1 | c.1050G>A p.R350= | Silent (SNP) | VAF 119/403 reads (30%) | called by muse, mutect2, varscan2
- NSUN6 | c.825C>T p.I275= | Silent (SNP) | VAF 66/146 reads (45%) | catalogued as rs199588247; called by muse, mutect2, varscan2
- NT5C3A | c.294C>T p.C98= (on ENST00000610140 / NM_001374335.1; = p.C64= on NM_016489.13) | Silent (SNP) | VAF 68/219 reads (31%) | catalogued as rs772505363; called by muse, mutect2, varscan2
- NXPE4 | c.525C>T p.V175= | Silent (SNP) | VAF 118/412 reads (29%) | called by muse, mutect2, varscan2
- OR10G4 | c.315C>T p.F105= | Silent (SNP) | VAF 40/422 reads (9%) | catalogued as COSV100305051; called by muse, varscan2
- OR11H1 | c.198C>T p.F66= | Silent (SNP) | VAF 73/509 reads (14%) | catalogued as rs1460677549; called by muse, mutect2, varscan2
- OR13C5 | c.531C>T p.F177= | Silent (SNP) | VAF 68/160 reads (43%) | catalogued as COSV66165252; called by muse, varscan2
- OR2AG2 | c.249G>A p.A83= | Silent (SNP) | VAF 85/338 reads (25%) | catalogued as rs377202637; called by muse, mutect2, varscan2
- OR4C46 | c.891G>A p.R297= | Silent (SNP) | VAF 36/176 reads (20%) | catalogued as COSV60218799; called by muse, mutect2
- OR51E2 | c.141C>T p.I47= | Silent (SNP) | VAF 108/330 reads (33%) | catalogued as rs752110405, COSV67806916; called by muse, mutect2, varscan2
- OR5AR1 | c.543C>T p.I181= | Silent (SNP) | VAF 87/273 reads (32%) | catalogued as COSV57253855; called by muse, mutect2, varscan2
- OR7G1 | c.78C>T p.I26= | Silent (SNP) | VAF 28/339 reads (8%) | catalogued as rs761369127, COSV53317668; called by muse, mutect2
- OTOF | c.3123C>T p.S1041= (on ENST00000272371 / NM_194248.3; = p.S294= on NM_004802.4) | Silent (SNP) | VAF 39/186 reads (21%) | called by muse, mutect2, varscan2
- OTOGL | c.660T>C p.A220= (on ENST00000547103; = p.A211= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 76/258 reads (29%) | called by muse, mutect2, varscan2
- P2RX2 | c.330C>T p.I110= | Silent (SNP) | VAF 113/327 reads (35%) | called by muse, mutect2, varscan2
- PAX7 | c.549G>A p.K183= | Silent (SNP) | VAF 60/353 reads (17%) | catalogued as rs1184049164; called by muse, mutect2, varscan2
- PCDHB8 | c.345C>T p.F115= | Silent (SNP) | VAF 32/301 reads (11%) | catalogued as rs1217580341, COSV50787334; called by muse, mutect2, varscan2
- PCDHGB6 | c.1128C>T p.F376= | Silent (SNP) | VAF 86/284 reads (30%) | catalogued as rs920851409, COSV53929363; called by muse, mutect2, varscan2
- PCLO | c.2082C>T p.L694= | Silent (SNP) | VAF 136/436 reads (31%) | catalogued as COSV100426403; called by muse, mutect2, varscan2
- PCNX1 | c.3852C>T p.V1284= | Silent (SNP) | VAF 42/279 reads (15%) | called by muse, mutect2, varscan2
- PDE3A | c.3381G>A p.G1127= | Silent (SNP) | VAF 25/304 reads (8%) | catalogued as rs868554794; called by muse, mutect2
- PES1 | c.1290G>A p.K430= | Silent (SNP) | VAF 66/292 reads (23%) | called by muse, mutect2, varscan2
- PIDD1 | c.2460C>T p.I820= | Silent (SNP) | VAF 88/299 reads (29%) | called by muse, mutect2, varscan2
- PIFO | c.549G>A p.V183= | Silent (SNP) | VAF 66/258 reads (26%) | called by muse, mutect2, varscan2
- PKN1 | c.1020C>T p.I340= | Silent (SNP) | VAF 105/380 reads (28%) | catalogued as COSV54395896, COSV54396597; called by muse, mutect2, varscan2
- PKP1 | c.393C>T p.P131= | Silent (SNP) | VAF 44/549 reads (8%) | called by muse, mutect2
- PLA2R1 | c.348C>T p.R116= | Silent (SNP) | VAF 97/377 reads (26%) | catalogued as COSV99323423; called by muse, mutect2, varscan2
- PLAAT1 | c.783G>A p.L261= (on ENST00000650797; = p.L156= on NM_020386.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/370 reads (6%) | catalogued as rs1244205845; called by muse, mutect2
- PLEC | c.4305C>T p.S1435= (on ENST00000322810 / NM_201380.4; = p.S1325= on NM_000445.5) | Silent (SNP) | VAF 106/328 reads (32%) | catalogued as rs1554706428, COSV100511907; called by muse, mutect2, varscan2
- POP1 | c.1930T>C p.L644= | Silent (SNP) | VAF 53/253 reads (21%) | called by muse, mutect2, varscan2
- PPL | c.3273G>A p.L1091= | Silent (SNP) | VAF 139/411 reads (34%) | called by muse, mutect2, varscan2
- PPP6C | c.627C>T p.P209= | Silent (SNP) | VAF 81/181 reads (45%) | catalogued as COSV101001147; called by muse, mutect2, varscan2
- PRAMEF12 | c.1272C>T p.L424= | Silent (SNP) | VAF 103/342 reads (30%) | catalogued as COSV100743014; called by muse, mutect2, varscan2
- PRAMEF4 | c.1350C>T p.P450= | Silent (SNP) | VAF 60/269 reads (22%) | called by muse, mutect2, varscan2
- PRAMEF6 | c.1430G>A p.*477= | Silent (SNP) | VAF 36/146 reads (25%) | called by muse, mutect2, varscan2
- PRKG1 | c.1332G>A p.K444= | Silent (SNP) | VAF 64/133 reads (48%) | catalogued as COSV100907476; called by muse, mutect2, varscan2
- PRPF8 | c.4623C>T p.T1541= | Silent (SNP) | VAF 68/217 reads (31%) | called by muse, mutect2, varscan2
- PRR16 | c.885C>T p.I295= (on ENST00000407149 / NM_001300783.2; = p.I272= on NM_016644.2) | Silent (SNP) | VAF 70/292 reads (24%) | catalogued as COSV101087138; called by muse, mutect2, varscan2
- QTRT1 | c.594C>T p.F198= | Silent (SNP) | VAF 96/256 reads (38%) | catalogued as rs759779117, COSV51550844; called by muse, mutect2, varscan2
- RABAC1 | c.507C>T p.F169= | Silent (SNP) | VAF 77/297 reads (26%) | catalogued as COSV99706006; called by muse, mutect2, varscan2
- RNF213 | c.3081C>T p.I1027= | Silent (SNP) | VAF 30/382 reads (8%) | catalogued as rs774940630; called by muse, mutect2
- ROBO2 | c.93G>A p.G31= | Silent (SNP) | VAF 77/219 reads (35%) | catalogued as COSV101533692; called by muse, mutect2, varscan2
- ROBO4 | c.2664C>T p.A888= | Silent (SNP) | VAF 135/413 reads (33%) | called by muse, mutect2, varscan2
- RREB1 | c.4113C>T p.D1371= | Silent (SNP) | VAF 72/565 reads (13%) | called by muse, mutect2, varscan2
- RYR2 | c.11526C>T p.F3842= | Silent (SNP) | VAF 41/244 reads (17%) | called by muse, mutect2, varscan2
- SBSN | c.1413G>A p.K471= (on ENST00000452271 / NM_001166034.2; = p.K128= on NM_198538.4) | Silent (SNP) | VAF 93/336 reads (28%) | called by muse, mutect2, varscan2
- SCN10A | c.1146C>T p.F382= | Silent (SNP) | VAF 100/300 reads (33%) | catalogued as rs1362320697, COSV101479299; called by muse, mutect2, varscan2
- SCN1A | c.39C>T p.S13= | Silent (SNP) | VAF 65/266 reads (24%) | called by muse, mutect2, varscan2
- SCUBE1 | c.2508C>T p.I836= | Silent (SNP) | VAF 100/314 reads (32%) | called by muse, mutect2, varscan2
- SDF4 | c.864C>T p.D288= | Silent (SNP) | VAF 22/318 reads (7%) | catalogued as rs767465020; called by muse, mutect2
- SETDB1 | c.1798C>T p.L600= | Silent (SNP) | VAF 42/562 reads (7%) | catalogued as rs587760501; called by muse, mutect2
- SH2B3 | c.294C>T p.A98= | Silent (SNP) | VAF 122/498 reads (24%) | called by muse, mutect2, varscan2
- SH3TC1 | c.2274C>T p.P758= | Silent (SNP) | VAF 38/485 reads (8%) | catalogued as rs1377408190; called by muse, mutect2
- SHKBP1 | c.1881C>T p.I627= | Silent (SNP) | VAF 70/273 reads (26%) | called by muse, mutect2, varscan2
92 further variants in this file (0 protein-altering or splice-affecting, 57 silent, 35 other) are not listed here.
